Gene-level copy-number profile of tumor specimen TCGA-12-1602-01A from TCGA case TCGA-12-1602, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.8 years (21,492 days).
Specimen TCGA-12-1602-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.f6c0e273-e820-402b-93bb-00e80e63f680.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-1602-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13a3cf27-1001-4529-bd66-b2bc99d473fb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 784; copy number 2: 12,106; copy number 3: 28,510; copy number 4: 15,752; copy number 5: 1,810; copy number 6: 755; copy number 9: 4; copy number 10: 7; copy number 15: 5; copy number 26: 50; copy number 31: 1; copy number 35: 5; copy number 36: 6; copy number 38: 2; copy number 42: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-1602-01A-01D-0591-01): tumor purity 0.81, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,659,613–88,700,401, 17 genes (within-gene range 0–2): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1.
- chr10:88,727,485–88,728,914, 1 gene: KRT8P38.
- chr11:41,993,381–42,163,851, 1 gene: LINC02745.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 81 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:53,006,282–53,102,345, 7 genes, copy number 10: EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6.
- chr12:55,434,734–55,585,471, 5 genes, copy number 15 (within-gene range 2–15): AC122685.1, OR6C2, OR6C70, OR6C68, OR6C64P.
- chr12:57,457,596–58,244,865, 50 genes, copy number 26: AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr12:61,600,067–62,279,150, 6 genes, copy number 9–38 (within-gene range 2–38): DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6.
- chr12:62,334,091–62,334,197, 1 gene, copy number 38: RNU6-595P.
- chr12:63,002,469–63,055,765, 4 genes, copy number 9–42: AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5.
- chr12:63,760,358–63,822,156, 3 genes, copy number 36 (within-gene range 2–36): AC084357.1, RXYLT1, RXYLT1-AS1.
- chr12:68,805,011–68,850,686, 5 genes, copy number 35: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.

Autosomal genes at a single copy (total copy number 1): 784. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
